TCGA case TCGA-24-1930 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: Washington University. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/62efb5ae-43dc-4a4c-a898-6cd9c6dba027

Demographics
Sex at birth: female; Race: white; Age at index: 53 years; Vital status: Dead; Days to death: 2,467 days (6.8 years).

Diagnoses (2)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 53.1 years (19,387 days); Year of diagnosis: 1998; Method of diagnosis: Surgical Resection; FIGO stage: Stage IIIC; Tumor grade: G3; Prior treatment: No.
   Pathology details: Residual tumor measurement: 1-10 mm.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Amifostine; Treatment intent type: Adjuvant; Days to treatment start: 14 days; Days to treatment end: 274 days; Number of cycles: 13; Treatment dose: 1,960 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Days to treatment start: 14 days; Days to treatment end: 274 days; Number of cycles: 13; Treatment dose: 4,020 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Treatment intent type: Adjuvant; Days to treatment start: 14 days; Days to treatment end: 274 days; Number of cycles: 13; Treatment dose: 518 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 14 days; Days to treatment end: 274 days; Number of cycles: 13; Treatment dose: 2,286 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Clinical Trial; Initial disease status: Recurrent Disease; Days to treatment start: 547 days (1.5 years); Days to treatment end: 631 days (1.7 years); Number of cycles: 5; Route of administration: Intravenous.
   Treatment given: Treatment type: Radiation, External Beam; Initial disease status: Recurrent Disease; Days to treatment start: 684 days (1.9 years); Days to treatment end: 707 days (1.9 years); Treatment dose: 3,750 cGy; Treatment anatomic sites: Distant Site.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Topotecan; Initial disease status: Progressive Disease; Days to treatment start: 726 days (2.0 years); Days to treatment end: 1,083 days (3.0 years); Number of cycles: 12; Treatment dose: 95 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Initial disease status: Progressive Disease; Days to treatment start: 1,112 days (3.0 years); Days to treatment end: 1,112 days (3.0 years); Number of cycles: 1; Treatment dose: 450 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Initial disease status: Progressive Disease; Days to treatment start: 1,112 days (3.0 years); Days to treatment end: 1,112 days (3.0 years); Number of cycles: 1; Treatment dose: 305 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Initial disease status: Progressive Disease; Days to treatment start: 1,135 days (3.1 years); Days to treatment end: 1,275 days (3.5 years); Number of cycles: 7; Treatment dose: 3,170 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Pegylated Liposomal Doxorubicin Hydrochloride; Initial disease status: Progressive Disease; Days to treatment start: 1,331 days (3.6 years); Days to treatment end: 1,389 days (3.8 years); Number of cycles: 3; Treatment dose: 218 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine; Initial disease status: Progressive Disease; Days to treatment start: 1,422 days (3.9 years); Days to treatment end: 1,475 days (4.0 years); Number of cycles: 3; Treatment dose: 11,435 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Altretamine; Initial disease status: Progressive Disease; Days to treatment start: 1,492 days (4.1 years); Days to treatment end: 1,684 days (4.6 years); Number of cycles: 7; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Topotecan; Initial disease status: Progressive Disease; Days to treatment start: 2,052 days (5.6 years); Days to treatment end: 2,144 days (5.9 years); Number of cycles: 5; Treatment dose: 45 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Vinorelbine Tartrate; Initial disease status: Progressive Disease; Days to treatment start: 2,052 days (5.6 years); Days to treatment end: 2,144 days (5.9 years); Number of cycles: 5; Treatment dose: 448 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Initial disease status: Progressive Disease; Days to treatment start: 2,164 days (5.9 years); Days to treatment end: 2,325 days (6.4 years); Number of cycles: 8; Treatment dose: 896 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine Hydrochloride; Initial disease status: Progressive Disease; Days to treatment start: 2,164 days (5.9 years); Days to treatment end: 2,325 days (6.4 years); Number of cycles: 8; Treatment dose: 23,008 mg; Route of administration: Intravenous.
2. Metastasis of diagnosis 1 (Serous cystadenocarcinoma, NOS). Age at diagnosis: 54.6 years (19,931 days); Days to diagnosis: 544 days (1.5 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 670 days (1.8 years).
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 1,923 days (5.3 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Recurrent Disease.

Follow-up (5 entries)
- Day 544 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 544 days (1.5 years); Evidence of recurrence type: Convincing Image Source.
- Days to follow up: 2,467 days (6.8 years); Disease response: With Tumor.
- Karnofsky performance status: 100; ECOG performance status: 0; Timepoint: Post Adjuvant Therapy.
- Progression or recurrence: Yes; Progression or recurrence type: Distant; Evidence of progression type: Convincing Image Source; Timepoint: Post Initial Treatment.
- Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Evidence of recurrence type: Convincing Image Source; Timepoint: Post Initial Treatment.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-24-1930-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1; Intermediate dimension: 1; Shortest dimension: 0.6.
  Slide TCGA-24-1930-01A-01-BS1: Section location: Bottom; Percent tumor cells: 90; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide TCGA-24-1930-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-24-1930-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: With tumor; History neoadjuvant treatment: No; Performance status timing: Post-Adjuvant Therapy; Method initial path diagnosis: Tumor resection.
- Drug treatment 1: Pharmaceutical therapy drug name: Ovarex/placebo.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Pharmaceutical therapy drug name: Amitostin.
- Drug treatment 3: Therapy regimen: Progression.
- Drug treatment 8: Pharmaceutical therapy drug name: Taxol; Therapy regimen: Progression.
- Drug treatment 10: Pharmaceutical therapy drug name: Doxil; Therapy regimen: Progression.
- Drug treatment 13: Pharmaceutical therapy drug name: Gemzar; Therapy regimen: Progression.
- Drug treatment 15: Pharmaceutical therapy drug name: Navelbine; Therapy regimen: Progression.
- Drug treatment 16: Pharmaceutical therapy drug name: Hexamethymelamine; Therapy regimen: Progression.
- Drug treatment 16, Route of administrations: Route of administration: PO.
- Follow-up form: Treatment outcome first course: Complete Remission/Response; Tumor status: With tumor; Performance status timing: Post-Adjuvant Therapy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 2,467 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 2,467 days; disease-free interval: event (new tumor event after initially disease-free), 544 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 544 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-24-1930-01): tumor purity 0.66, ploidy 2.97, whole-genome doublings 1 (call status: legacy_call).
